Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6569, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6569-01A (Primary Tumor).

	LARGE INTESTINE TISSUE CHECKLIST
--	----------------------------------

	Specimen type: Hemicolectomy Specimen size: Not specified Tumor site: Colon Tumor size: 6.5 x 4.5 x 4 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Well differentiated Tumor extent: Muscularis propria Lymph nodes: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	--

Source: NCI Genomic Data Commons file 0cb79421-f1b5-40a4-8ab1-6b06d03b8420 (TCGA-F4-6569.7AB8BD50-444E-48EB-BB37-3B64FECFEFE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).